Somatic mutation profile of tumor specimen ER-B0CR-TTP1-A (aliquot ER-B0CR-TTP1-A-1-0-D-A670-35) from EXCEPTIONAL_RESPONDERS case ER-B0CR, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.3 years (23,120 days).
Specimen ER-B0CR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d6ce321-127b-4271-810d-c6a8751e4c11.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-B0CR-NT1-A (Solid Tissue Normal), aliquot ER-B0CR-NT1-A-1-0-D-A670-35; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84a1cb4a-96f7-465b-86b4-ba8b9f40d052

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4645C>T p.Q1549* | Nonsense Mutation (SNP) | VAF 84/564 reads (15%) | catalogued as rs863225357, COSV57334229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3469C>T p.R1157W | Missense Mutation (SNP) | VAF 34/463 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM122495, COSV60789213; called by muse, mutect2
- EPHA6 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 29/418 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs779122297; called by muse, mutect2
- ESR1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 85/396 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779180038, COSV52782036; called by muse, mutect2, varscan2
- APC | c.2868_2872del p.Y956* | Frame Shift Del (DEL) | VAF 61/531 reads (11%) | called by mutect2, pindel, varscan2
- BTK | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- INSR | c.645C>T p.C215= | Silent (SNP) | VAF 51/432 reads (12%) | called by muse, mutect2, varscan2
- LRP1B | c.11655T>A p.S3885= | Silent (SNP) | VAF 46/592 reads (8%) | called by muse, mutect2
